Gene-level copy-number profile of tumor specimen TCGA-AJ-A3QS-01A from TCGA case TCGA-AJ-A3QS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 57.9 years (21,162 days).
Specimen TCGA-AJ-A3QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.49f6700a-5b48-47f7-939b-002c1862212c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AJ-A3QS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5a1e7b71-0bd9-46a4-ba47-bdc2898139b7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,056; copy number 2: 7,587; copy number 3: 25,271; copy number 4: 18,161; copy number 5: 3,982; copy number 6: 2,260; copy number 7: 335; copy number 8: 366; copy number 9: 123; copy number 10: 313; copy number 11: 45; copy number 12: 1; copy number 13: 6; copy number 14: 114; copy number 15: 171; copy number 18: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AJ-A3QS-01A-11D-A227-01): tumor purity 0.47, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,500 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:93,846,832–96,696,167, 57 genes, copy number 10: MIR760, AL049796.1, DNTTIP2, GCLM, CHCHD2P5, MTND4P11, MTND3P21, MTCO3P21, MTATP6P13, AL117351.2, MTCO2P21, MTCO1P21, AL117351.1, ABCA4, AC093579.1, ARHGAP29, RN7SL440P, ARHGAP29-AS1, GAPDHP29, AC097059.1, AC118469.1, AC118469.2, ABCD3, F3, AC093117.1, SLC44A3-AS1, KATNBL1P2, MIR378G, SLC44A3, CNN3, AC105942.1, ALG14, ALG14-AS1, TLCD4, TLCD4-RWDD3, AC092802.3, Y_RNA, AC092802.1, RWDD3, AC092802.2, AC092802.4, LINC01760, LINC01650, AL445218.1, LINC01761, LINC02607, AL683887.1, LINC02790, RNU1-130P, LINC01787, AC092393.1, UBE2WP1, EEF1A1P11, RN7SL831P, NDUFS5P2, RPL7P9, RN7SKP270.
- chr1:101,270,875–103,758,690, 25 genes, copy number 8–11: PPIAP7, LINC01307, LINC01709, RNU6-965P, RPSAP19, OLFM3, RNU6-352P, AL356280.1, DNAJA1P5, AC114485.1, AC099567.1, COL11A1, SOD2P1, AC095032.2, AC095032.1, RN7SKP285, RNPC3, AMY2B, ACTG1P4, AMY2A, AMY1A, AC105272.1, AMY1B, AMYP1, AMY1C.
- chr1:117,111,060–117,365,473, 6 genes, copy number 7: TRIM45, RPS15AP9, VTCN1, Metazoa_SRP, LINC01525, AL358072.1.
- chr2:490,944–5,314,134, 65 genes, copy number 8–10 (broad region; genes not listed).
- chr2:7,922,425–8,278,186, 1 gene, copy number 10 (within-gene range 6–10): LINC00298.
- chr2:7,988,683–9,934,416, 32 genes, copy number 9–10 (within-gene range 3–10): LINC00299, U91324.1, LINC01814, AC092617.1, AC011747.1, SNRPEP5, ID2-AS1, ID2, KIDINS220, MBOAT2, HMGB1P25, RPL30P3, AC093904.2, AC093904.4, AC093904.3, AC093904.1, ASAP2, EIF1P7, ITGB1BP1, CPSF3, IAH1, ADAM17, AC080162.1, AC073195.1, YWHAQ, Y_RNA, AC082651.1, AC082651.4, RNU4-73P, AC082651.2, AC082651.3, TAF1B.
- chr2:55,282,350–55,346,049, 1 gene, copy number 9 (within-gene range 6–9): AC012358.2.
- chr2:55,287,842–56,181,652, 18 genes, copy number 9 (within-gene range 6–9): CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P, CFAP36, PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813.
- chr2:56,173,534–56,185,870, 1 gene, copy number 9: AC007743.1.
- chr2:58,427,799–59,063,766, 1 gene, copy number 7 (within-gene range 6–7): LINC01122.
- chr2:59,014,354–62,224,731, 66 genes, copy number 7 (broad region; genes not listed).
- chr2:99,545,419–101,894,689, 39 genes, copy number 9 (within-gene range 5–9): AFF3, AC092667.1, LINC01104, LONRF2, CYCSP7, AC012493.1, CHST10, RALBP1P2, NMS, ARPP19P2, PDCL3, HMGN2P22, LINC01849, AC092845.1, NANOGNBP1, LINC01868, AC092168.1, AC092168.3, NPAS2, AC092168.2, NPAS2-AS1, AC016738.1, RPL31, TBC1D8, BBIP1P1, TBC1D8-AS1, CNOT11, RNF149, SNORD89, MIR5696, CREG2, AC092570.1, RFX8, LINC01870, RPS6P3, PRCPP1, AC093894.1, AC093894.2, MAP4K4.
- chr2:106,247,369–107,407,329, 22 genes, copy number 7: RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1, ANAPC1P6, PLGLA, RGPD3, AC097527.1, CD8B2, AC108868.2, AC108868.1, EEF1A1P12, ST6GAL2, ST6GAL2-IT1, AC016994.1, AC005040.2, PPP1R2P5, AC005040.1, LINC01789, AC096669.1.
- chr3:90,030,284–90,257,415, 3 genes, copy number 9: U3, RNU6-712P, PROS2P.
- chr3:169,447,867–170,396,835, 32 genes, copy number 7 (within-gene range 5–7): MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL.
- chr4:142,023,160–147,159,068, 77 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr7:8,433,609–10,085,494, 12 genes, copy number 7 (within-gene range 5–7): NXPH1, AC009500.1, AC004852.2, AC004852.1, AC004852.3, GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1.
- chr7:17,374,867–24,291,862, 98 genes, copy number 7–18 (within-gene range 5–18) (broad region; genes not listed).
- chr8:114,791,653–118,622,112, 25 genes, copy number 13–18 (within-gene range 6–18): CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1.
- chr8:140,657,900–141,518,737, 24 genes, copy number 7 (within-gene range 6–7): PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1.
- chr11:12,619,326–18,634,791, 125 genes, copy number 7–15 (broad region; genes not listed).
- chr14:89,794,669–90,491,637, 16 genes, copy number 7 (within-gene range 3–7): EFCAB11, RAB42P1, TDP1, KCNK13, GLRXP2, Y_RNA, PSMC1, NRDE2, AL161662.1, RPL21P11, AL512791.2, CALM1, AL512791.1, LINC02317, LINC00642, AL096869.3.
- chr14:90,567,495–90,569,976, 1 gene, copy number 7: AL096869.1.
- chr17:37,084,992–41,715,969, 234 genes, copy number 10–14 (within-gene range 5–14) (broad region; genes not listed).
- chr19:7,018,969–10,380,572, 180 genes, copy number 8–10 (broad region; genes not listed).
- chr19:27,638,483–32,244,083, 87 genes, copy number 7–12 (broad region; genes not listed).
- chr19:39,243,553–40,576,464, 79 genes, copy number 15 (within-gene range 4–15) (broad region; genes not listed).
- chr22:30,635,781–34,651,862, 110 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr22:38,952,741–40,682,814, 54 genes, copy number 7: APOBEC3A, APOBEC3B, APOBEC3B-AS1, APOBEC3C, AL022318.4, APOBEC3D, APOBEC3F, AL022318.2, APOBEC3G, AL031846.1, APOBEC3H, CBX7, COX5BP7, AL031846.2, FUNDC2P4, PDGFB, AL031590.1, AL022326.1, RPL3, SNORD83B, SNORD83A, SNORD43, SYNGR1, AL022326.2, TAB1, MGAT3, MGAT3-AS1, MIEF1, AL022312.1, ATF4, RPS19BP1, CACNA1I, ENTHD1, MTFR2P2, RN7SKP210, UQCRFS1P1, GRAP2, Z82206.1, FAM83F, Z83847.1, TNRC6B, RPL7P52, ADSL, AL022238.3, SGSM3, SGSM3-AS1, MRTFA, AL022238.2, AL022238.1, MRTFA-AS1, COX6B1P3, RPL4P6, GAPDHP37, MCHR1.
- chr22:48,320,412–48,489,324, 4 genes, copy number 9: AL008720.2, Z72006.1, Z82249.1, Z84468.2.
- chr22:48,538,900–48,547,387, 1 gene, copy number 9: Z84468.1.
- chr22:49,543,393–49,615,716, 4 genes, copy number 7: MIR3667, Z97192.1, Z97192.2, Z97192.3.

Autosomal genes at a single copy (total copy number 1): 878. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
